Somatic mutation profile of tumor specimen TCGA-D7-5578-01A (aliquot TCGA-D7-5578-01A-01D-1600-08) from TCGA case TCGA-D7-5578, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 80.5 years (29,390 days).
Specimen TCGA-D7-5578-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 820c4baf-66c3-4fa9-bfc6-9d84d1c781f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-5578-10A (Blood Derived Normal), aliquot TCGA-D7-5578-10A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afdcf306-2cab-4c3b-945d-f18d0f4b3d57

The open-access MAF lists 239 somatic variants for this specimen: 177 protein-altering or splice-affecting, 59 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 160, Silent 59, Nonsense Mutation 10, Frame Shift Del 3, Splice Region 2, RNA 2, 5'UTR 1, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 10/120 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- TP53 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 19/33 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1060501191, COSV52666332, COSV52700326, COSV52746468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA12 | c.1115G>T p.S372I (on ENST00000272895 / NM_173076.3; = p.S54I on NM_015657.3) | Missense Mutation (SNP) | VAF 84/320 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.254); catalogued as COSV55953519; called by muse, mutect2, varscan2
- ACSM6 | c.913-1G>C p.X305_splice | Splice Site (SNP) | VAF 27/146 reads (18%) | catalogued as COSV58977876; called by muse, mutect2, varscan2
- ACTN1 | c.2093C>T p.A698V | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV51988640; called by muse, mutect2, varscan2
- ADAMTS1 | c.2014G>C p.V672L | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV53169334; called by muse, mutect2
- ADGRB3 | c.1126C>G p.Q376E | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as COSV65389279; called by muse, mutect2, varscan2
- ADGRB3 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1485131142, COSV65389285; called by muse, mutect2, varscan2
- AFDN | c.3812G>A p.R1271H | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.584); catalogued as rs151265223; called by muse, mutect2, varscan2
- AFF2 | c.2603A>C p.K868T | Missense Mutation (SNP) | VAF 14/299 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV53975964, COSV53982508; called by muse, mutect2
- AGTRAP | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs951091449, COSV58668616; called by muse, mutect2, varscan2
- AHNAK2 | c.13025A>G p.K4342R | Missense Mutation (SNP) | VAF 109/366 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1435056613, COSV60911402; called by muse, mutect2, varscan2
- AKAP3 | c.2179G>T p.E727* | Nonsense Mutation (SNP) | VAF 13/107 reads (12%) | catalogued as COSV57415246; called by muse, mutect2, varscan2
- AMER1 | c.3335A>C p.E1112A | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV57657139; called by muse, mutect2, varscan2
- AMER2 | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 112/178 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63436764, COSV63439765; called by muse, mutect2, varscan2
- AR | c.2440T>G p.F814V | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101017553, COSV65954499; called by muse, mutect2, varscan2
- ATP2A1 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV59461589; called by muse, mutect2, varscan2
- ATR | c.4470G>T p.W1490C | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63385258; called by muse, mutect2, varscan2
- BMT2 | c.927A>C p.K309N | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51775713; called by muse, mutect2, varscan2
- C17orf97 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs376770602; called by muse, mutect2, varscan2
- CASKIN2 | c.1241G>T p.R414L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100050300; called by muse, mutect2, varscan2
- CDH11 | c.1931A>C p.K644T | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51755967, COSV99217324; called by muse, mutect2, varscan2
- CDH8 | c.1184C>A p.T395N | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV54856965; called by muse, varscan2
- CHRM2 | c.976A>G p.R326G | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.102); catalogued as COSV57768532; called by muse, mutect2, varscan2
- CMYA5 | c.6751G>A p.G2251S | Missense Mutation (SNP) | VAF 77/266 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.162); catalogued as COSV71404896; called by muse, mutect2, varscan2
- CNTN3 | c.2140C>T p.R714W | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs752462306, COSV55163360; called by muse, mutect2, varscan2
- COL1A2 | c.2546C>G p.S849C | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV51955373, COSV99798307; called by muse, mutect2, varscan2
- CTSW | c.943C>G p.Q315E | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV57172030; called by muse, mutect2
- CYLC1 | c.24A>C p.K8N | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV61410987; called by muse, mutect2, varscan2
- DCUN1D5 | c.522G>A p.W174* | Nonsense Mutation (SNP) | VAF 22/100 reads (22%) | catalogued as COSV52784145; called by muse, mutect2, varscan2
- DHX32 | c.1038G>T p.L346F | Missense Mutation (SNP) | VAF 66/222 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as COSV52939113; called by muse, varscan2
- DNAH11 | c.2690C>A p.A897D | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.936); catalogued as COSV60947769; called by muse, mutect2, varscan2
- DPYSL4 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs907829231, COSV58306659; called by muse, mutect2, varscan2
- EIF4B | c.893A>G p.Y298C | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1206228898, COSV50401995; called by muse, mutect2, varscan2
- EML1 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs200753382; called by muse, mutect2, varscan2
- ENTPD3 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); catalogued as rs892772401, COSV57193854; called by muse, mutect2, varscan2
- EPHA6 | c.1632G>T p.R544S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.597); catalogued as COSV67565320, COSV67588697; called by muse, mutect2, varscan2
- F10 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 78/131 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.147); catalogued as rs201675411, COSV65021200; called by muse, mutect2, varscan2
- FAM133A | c.747A>T p.*249Yext*8 | Nonstop Mutation (SNP) | VAF 50/86 reads (58%) | catalogued as COSV59074451; called by muse, mutect2, varscan2
- FAT4 | c.1711A>C p.T571P | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.429); catalogued as COSV67883254; called by muse, mutect2, varscan2
- FAT4 | c.10094G>A p.R3365Q | Missense Mutation (SNP) | VAF 124/382 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs752591843, COSV58677363, COSV58687881; called by muse, mutect2, varscan2
- FAT4 | c.10420A>C p.T3474P | Missense Mutation (SNP) | VAF 79/308 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV58677374, COSV58681090; called by muse, mutect2, varscan2
- FBXL12 | c.404A>G p.E135G | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56113861; called by muse, mutect2, varscan2
- FGF14 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 57/105 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65938810; called by muse, mutect2, varscan2
- FLRT2 | c.1238G>A p.G413D | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV58138695; called by muse, mutect2, varscan2
- FMO1 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61445135; called by muse, mutect2, varscan2
- FNTB | c.701A>G p.N234S | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV55760631; called by muse, mutect2, varscan2
- FOLR1 | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56615852; called by muse, mutect2, varscan2
- FSHR | c.438A>C p.K146N | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT tolerated (0.84); PolyPhen benign (0.028); catalogued as COSV58618791, COSV58620376, COSV58630781; called by muse, mutect2, varscan2
- GABRB3 | c.164T>A p.F55Y | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.445); catalogued as COSV59477592; called by muse, mutect2, varscan2
- GABRQ | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 75/110 reads (68%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.997); catalogued as rs782675594, COSV64781125; called by muse, mutect2, varscan2
- GNL2 | c.178C>G p.L60V | Missense Mutation (SNP) | VAF 22/307 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.348); catalogued as COSV100895043, COSV66079903; called by muse, mutect2
- GPR146 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs142169372, COSV52465462; called by muse, mutect2, varscan2
- GRIK2 | c.253C>A p.L85I | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs143873289, COSV59723631; called by muse, mutect2, varscan2
- GYS2 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 41/173 reads (24%) | catalogued as COSV53921586; called by muse, mutect2, varscan2
- HEPACAM2 | c.1199C>A p.S400* (on ENST00000394468 / NM_001039372.4; = p.S388* on NM_198151.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 40/164 reads (24%) | catalogued as COSV59059082; called by muse, varscan2
- HEPHL1 | c.3097C>T p.Q1033* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as COSV59890553; called by muse, mutect2, varscan2
- HNRNPLL | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as COSV55367209; called by muse, mutect2
- HPS6 | c.1457C>A p.A486E | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV54625210; called by muse, mutect2, varscan2
- IL1RAPL2 | c.609A>C p.E203D | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV61148447; called by muse, mutect2, varscan2
- ITGB2 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs548099370, COSV56608064; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- JAKMIP1 | c.896C>A p.S299* | Nonsense Mutation (SNP) | VAF 131/553 reads (24%) | catalogued as COSV51525749; called by muse, mutect2, varscan2
- KSR2 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 73/237 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs756996528, COSV60370733; called by muse, mutect2, varscan2
- LMLN | c.793G>C p.G265R | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.18); catalogued as COSV57599227; called by muse, mutect2, varscan2
- LRRN1 | c.1504C>G p.Q502E | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV60012200, COSV60013136; called by muse, mutect2, varscan2
- LRRN3 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57818182; called by muse, mutect2, varscan2
- LZTR1 | c.1210G>A p.G404R | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1470449160, CM140926, COSV53146242; called by muse, mutect2, varscan2
- MAB21L1 | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); catalogued as COSV59770193, COSV59788314; called by muse, mutect2, varscan2
- MAGEC3 | c.1555G>T p.D519Y | Missense Mutation (SNP) | VAF 124/201 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs752119740, COSV53577178, COSV53577908; called by muse, mutect2, varscan2
- MDN1 | c.14605A>G p.N4869D | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.165); catalogued as COSV65519369; called by muse, mutect2, varscan2
- MDN1 | c.3817C>T p.R1273C | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65517497; called by muse, mutect2, varscan2
- MLLT11 | c.94C>G p.L32V | Missense Mutation (SNP) | VAF 64/254 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); catalogued as COSV64462138; called by muse, mutect2, varscan2
- MSTO1 | c.1301C>A p.T434K | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.218); catalogued as COSV55471600; called by muse, mutect2, varscan2
- MYH11 | c.5833C>T p.R1945C | Missense Mutation (SNP) | VAF 71/301 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs751862398, COSV55547070; called by muse, mutect2, varscan2
- MYH7 | c.4052C>T p.T1351M | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs370403289, CM068017; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK | c.2710A>C p.K904Q | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV60607403; called by muse, mutect2, varscan2
- MYO5C | c.2524C>T p.R842* | Nonsense Mutation (SNP) | VAF 15/382 reads (4%) | catalogued as rs999922874, COSV55904334; called by muse, mutect2
- MYT1 | c.372G>C p.E124D | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV60503065; called by muse, mutect2, varscan2
- NAV3 | c.3764A>T p.K1255M | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57070075; called by muse, mutect2, varscan2
- NBEA | c.2985A>C p.K995N | Missense Mutation (SNP) | VAF 96/160 reads (60%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.188); catalogued as COSV59770179, COSV59815455; called by muse, mutect2, varscan2
- NCAPG | c.2978G>A p.R993Q | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs757772284, COSV52268755; called by muse, mutect2, varscan2
- NCOA2 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 176/973 reads (18%) | catalogued as COSV71763713; called by muse, mutect2, varscan2
- NCOR1 | c.1238G>A p.R413K | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV51968302; called by muse, mutect2, varscan2
- NEB | c.15569T>G p.L5190R | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50898981; called by muse, mutect2, varscan2
- NECAB2 | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs757750776, COSV59419875; called by muse, mutect2, varscan2
- NEDD4 | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as rs146216406, COSV59060173; called by muse, mutect2
- NOSTRIN | c.707T>C p.L236P (on ENST00000317647 / NM_001039724.4; = p.L158P on NM_052946.3) | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.07); catalogued as COSV58320253; called by muse, mutect2, varscan2
- NOTCH2 | c.5399G>A p.R1800H | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1264016887, COSV56686807; called by muse, mutect2, varscan2
- NPFF | c.254G>A p.R85K | Missense Mutation (SNP) | VAF 93/333 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1565904408, COSV57199282; called by muse, mutect2, varscan2
- NPR1 | c.1031G>A p.G344D | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV64140655; called by muse, mutect2, varscan2
- NR3C2 | c.1862G>A p.G621D | Missense Mutation (SNP) | VAF 13/319 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1297567991, COSV60987587; called by muse, mutect2
- NRG3 | c.1065A>C p.E355D | Missense Mutation (SNP) | VAF 50/233 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV64552178; called by muse, mutect2, varscan2
- NUFIP2 | c.1327C>G p.L443V | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs140549572, COSV56602705; called by muse, mutect2, varscan2
- NUP98 | c.5341C>T p.R1781C (on ENST00000359171 / NM_001365126.1; = p.R1764C on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs766745271, COSV51709120; called by muse, mutect2
- ODF2L | c.1146T>C p.T382= (on ENST00000317336; = p.T353= on NM_020729.3) | Splice Region (SNP) | VAF 39/160 reads (24%) | catalogued as COSV54014635; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 28/110 reads (25%) | catalogued as rs761899382; called by mutect2, varscan2
- OR2Z1 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.01); catalogued as COSV60692028; called by muse, mutect2, varscan2
- OR3A2 | c.625T>A p.F209I | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV68695012; called by muse, mutect2, varscan2
- OR4A47 | c.182T>C p.L61P | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV71444881; called by muse, mutect2, varscan2
- OR4C16 | c.403A>C p.S135R | Missense Mutation (SNP) | VAF 72/281 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs1404669415, COSV58940425, COSV58941301, COSV58942700; called by muse, mutect2, varscan2
- OR4C6 | c.28T>A p.F10I | Missense Mutation (SNP) | VAF 72/270 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58603059, COSV58604627; called by muse, mutect2, varscan2
- OR4M1 | c.614T>C p.L205P | Missense Mutation (SNP) | VAF 123/629 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV60060239; called by muse, mutect2, varscan2
- OR5T1 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs143790336; called by muse, mutect2, varscan2
- OR5T2 | c.202T>G p.F68V | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as COSV57588421; called by muse, mutect2, varscan2
- OR8H3 | c.167T>G p.L56R | Missense Mutation (SNP) | VAF 140/718 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100538791, COSV57908101, COSV57910433; called by muse, mutect2, varscan2
- PCDHA10 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.957); catalogued as COSV56481854; called by muse, mutect2, varscan2
- PCDHA10 | c.1403C>T p.P468L | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.615); catalogued as rs782451627, COSV56488063; called by muse, mutect2, varscan2
- PCDHB13 | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.554); catalogued as COSV53394606, COSV99507576; called by muse, mutect2, varscan2
- PCDHB8 | c.1963G>C p.A655P | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.25); catalogued as COSV99176760; called by muse, mutect2, varscan2
- PCDHGA4 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.037); catalogued as COSV53919797; called by muse, mutect2, varscan2
- PCYT2 | c.539G>A p.C180Y | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.296); catalogued as COSV58710991; called by muse, mutect2, varscan2
- PDE3A | c.3413A>C p.K1138T | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV62970220; called by muse, mutect2, varscan2
- PGLYRP3 | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 69/272 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs374163212; called by muse, mutect2, varscan2
- PLEKHG7 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs115752910, COSV60821400; called by muse, mutect2, varscan2
- PTCH2 | c.2791C>T p.R931W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs569459197, COSV100942135, COSV64710418; called by muse, mutect2, varscan2
- PTPRD | c.1320A>C p.E440D | Missense Mutation (SNP) | VAF 102/252 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.811); catalogued as COSV61935527; called by muse, mutect2, varscan2
- PWWP3B | c.659T>C p.V220A | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV61798872; called by muse, mutect2, varscan2
- PXDNL | c.826T>G p.L276V | Missense Mutation (SNP) | VAF 76/528 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.06); catalogued as rs922527347, COSV62483422; called by muse, mutect2, varscan2
- PXDNL | c.757T>G p.F253V | Missense Mutation (SNP) | VAF 57/364 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62483430; called by muse, mutect2, varscan2
- RAB5B | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs781238057, COSV64364786; called by muse, mutect2, varscan2
- RD3 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.482); catalogued as rs777789102, COSV65362087; called by muse, mutect2, varscan2
- RHBDD1 | c.242T>C p.L81S | Missense Mutation (SNP) | VAF 63/275 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58125478; called by muse, mutect2, varscan2
- RIMS2 | c.1496A>T p.H499L (on ENST00000666250 / NM_001348490.2; = p.H307L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV51666221; called by muse, mutect2, varscan2
- RIMS2 | c.4034G>T p.S1345I | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV51666279; called by muse, mutect2, varscan2
- RIT2 | c.438A>C p.E146D | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.548); catalogued as COSV58662103; called by muse, mutect2, varscan2
- RRS1 | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52554132; called by muse, mutect2
- RXFP1 | c.1468T>G p.S490A | Missense Mutation (SNP) | VAF 35/316 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.142); catalogued as COSV57048181; called by muse, mutect2, varscan2
- RYR1 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 75/230 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.898); catalogued as COSV62093194; called by muse, mutect2, varscan2
- RYR2 | c.3709G>C p.E1237Q | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV63670391, COSV63674516; called by muse, mutect2, varscan2
- RYR2 | c.4916T>C p.V1639A | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV63674520; called by muse, mutect2, varscan2
- SALL2 | c.1615G>A p.V539M | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.575); catalogued as COSV58102553; called by muse, mutect2, varscan2
- SARAF | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs376298309; called by muse, mutect2, varscan2
- SDC4 | c.535A>G p.S179G | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV65595264; called by muse, mutect2, varscan2
- SLC1A6 | c.1453T>A p.L485M | Missense Mutation (SNP) | VAF 10/243 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55669153; called by muse, mutect2
- SLC22A23 | c.2009C>T p.A670V | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs754651871, COSV66676984; called by muse, mutect2, varscan2
- SLC25A25 | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as rs936575026, COSV66085918; called by muse, mutect2, varscan2
- SLITRK6 | c.120A>C p.K40N | Missense Mutation (SNP) | VAF 68/245 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV68389739; called by muse, mutect2, varscan2
- SNTB1 | c.1037T>G p.V346G | Missense Mutation (SNP) | VAF 59/572 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV67325337; called by muse, mutect2, varscan2
- SPHKAP | c.3229C>T p.R1077W | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755381681, COSV60872928; called by muse, mutect2, varscan2
- SPON1 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.197); catalogued as rs369560786; called by muse, mutect2, varscan2
- SPTA1 | c.820A>G p.T274A | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV63750866; called by muse, mutect2, varscan2
- ST3GAL6 | c.738A>C p.K246N | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV54580153, COSV54581667; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.596T>A p.V199D | Missense Mutation (SNP) | VAF 46/147 reads (31%) | PolyPhen probably damaging (0.962); catalogued as COSV60326360; called by muse, mutect2, varscan2
- STAB2 | c.7490C>A p.S2497* | Nonsense Mutation (SNP) | VAF 178/583 reads (31%) | catalogued as rs757626549, COSV66336891; called by muse, mutect2, varscan2
- STX19 | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 62/331 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV57397125; called by muse, mutect2, varscan2
- SUGP1 | c.806A>G p.K269R | Missense Mutation (SNP) | VAF 367/523 reads (70%) | SIFT tolerated (0.16); PolyPhen benign (0.394); catalogued as COSV55920811; called by muse, mutect2, varscan2
- SULF1 | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.775); catalogued as rs202168144, COSV52677324; called by muse, mutect2, varscan2
- SVEP1 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs548514380, COSV57027534; called by muse, mutect2, varscan2
- SYT16 | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761346026, COSV70855321; called by muse, varscan2
- TAS1R2 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs371743265; called by muse, mutect2, varscan2
- TCHH | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 80/301 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.212); catalogued as COSV64273800; called by muse, mutect2, varscan2
- TOP3A | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772020353, COSV58176173; called by muse, mutect2, varscan2
- TRAPPC12 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60846268; called by muse, mutect2
- TRAPPC9 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 11/214 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV66895667; called by muse, mutect2
- TULP3 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764071522, COSV68117585; called by muse, mutect2, varscan2
- UNC93B1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs754100504, COSV57098392; called by muse, mutect2
- USP17L2 | c.1478C>A p.T493N | Missense Mutation (SNP) | VAF 34/717 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1353324058, COSV61555659; called by muse, mutect2
- WBP11 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 76/232 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV53762315; called by muse, mutect2, varscan2
- YIPF7 | c.809T>A p.L270H | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100274383, COSV100274746, COSV60656371; called by muse, mutect2, varscan2
- ZNF329 | c.515A>C p.K172T | Missense Mutation (SNP) | VAF 87/243 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV63771991; called by muse, mutect2, varscan2
- ZNF43 | c.404A>G p.N135S | Missense Mutation (SNP) | VAF 67/248 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV61683402, COSV61684777; called by muse, mutect2, varscan2
- ZNF493 | c.560A>G p.H187R | Missense Mutation (SNP) | VAF 275/378 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs949508582, COSV62749533; called by muse, mutect2, varscan2
- ZNF536 | c.3814A>G p.S1272G | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.97); catalogued as COSV62821325; called by muse, mutect2, varscan2
- ZNF569 | c.1062T>A p.Y354* | Nonsense Mutation (SNP) | VAF 82/286 reads (29%) | catalogued as COSV100386406; called by muse, mutect2, varscan2
- ZNF569 | c.1061A>T p.Y354F | Missense Mutation (SNP) | VAF 81/285 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as COSV100386409; called by muse, mutect2, varscan2
- ZNF681 | c.647A>C p.H216P | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV68073901; called by muse, mutect2, varscan2
- ZNF804A | c.3041G>A p.G1014D | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs1318862821, COSV56441357; called by muse, mutect2, varscan2
- ZNF831 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64038648; called by muse, mutect2, varscan2
- ZNF98 | c.1190A>C p.K397T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1244217472, COSV100757398; called by mutect2, varscan2
- ANKRD20A1 | c.968G>C p.G323A | Missense Mutation (SNP) | VAF 49/388 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- BRIX1 | c.510+4del | Splice Region (DEL) | VAF 94/406 reads (23%) | called by mutect2, pindel, varscan2
- IGHM | c.805A>C p.T269P | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- OR56B1 | c.390_391del p.D130Efs*46 | Frame Shift Del (DEL) | VAF 22/115 reads (19%) | called by mutect2, pindel, varscan2
- PRAMEF15 | c.360A>C p.E120D | Missense Mutation (SNP) | VAF 154/759 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- PRAMEF19 | c.1190T>C p.L397P | Missense Mutation (SNP) | VAF 55/540 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRAV5 | c.325T>G p.F109V | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- TTC3 | c.992del p.N331Mfs*9 | Frame Shift Del (DEL) | VAF 42/158 reads (27%) | called by mutect2, pindel, varscan2
- ABCC10 | c.282C>T p.G94= (on ENST00000372530 / NM_001198934.2; = p.G51= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/126 reads (19%) | catalogued as COSV55085927; called by muse, mutect2, varscan2
- ADAM29 | c.267C>T p.I89= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as COSV63662044, COSV63662211, COSV63663536; called by muse, mutect2, varscan2
- ADARB1 | c.1371C>T p.F457= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV62343081; called by muse, mutect2, varscan2
- APBB1IP | c.678G>A p.P226= | Silent (SNP) | VAF 39/164 reads (24%) | catalogued as rs142075664; called by muse, mutect2, varscan2
- APC | c.3087T>G p.L1029= | Silent (SNP) | VAF 55/173 reads (32%) | catalogued as COSV57333782; called by muse, mutect2, varscan2
- ARNT2 | c.63G>A p.T21= | Silent (SNP) | VAF 92/284 reads (32%) | catalogued as rs745975276, COSV57583070; called by muse, mutect2, varscan2
- ATRX | c.546A>G p.Q182= | Silent (SNP) | VAF 102/165 reads (62%) | catalogued as rs375794120, COSV64869434; ClinVar: likely benign; called by muse, mutect2, varscan2
- BAIAP2 | c.834G>T p.P278= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV58334076; called by muse, mutect2, varscan2
- BHMT | c.594C>T p.P198= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as rs1166597087, COSV57153814, COSV57153962; called by muse, mutect2
- C2orf78 | c.867G>T p.G289= | Silent (SNP) | VAF 27/163 reads (17%) | catalogued as COSV68516924; called by muse, mutect2, varscan2
- CACNA1B | c.2142C>T p.N714= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as rs570622319, COSV53119959; called by muse, mutect2, varscan2
- CACNA1I | c.756C>T p.A252= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV60803940; called by muse, varscan2
- CACNG5 | c.534G>A p.S178= | Silent (SNP) | VAF 52/184 reads (28%) | catalogued as rs755332057, COSV50054718; called by muse, mutect2, varscan2
- CBLN1 | c.426C>T p.F142= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV54653642; called by muse, mutect2, varscan2
- CCNA1 | c.906G>A p.E302= | Silent (SNP) | VAF 64/108 reads (59%) | catalogued as COSV55220690; called by muse, mutect2, varscan2
- CFAP45 | c.1299C>T p.H433= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV63648058; called by muse, mutect2, varscan2
- CSMD1 | c.1260C>T p.S420= (on ENST00000520002; = p.S419= on NM_033225.6) | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as rs375954521, COSV68184110; called by muse, mutect2, varscan2
- CTNND2 | c.1659G>A p.P553= | Silent (SNP) | VAF 51/185 reads (28%) | catalogued as rs372124459; called by muse, mutect2, varscan2
- CYLC1 | c.1572T>C p.F524= | Silent (SNP) | VAF 37/61 reads (61%) | catalogued as COSV61410996; called by muse, mutect2, varscan2
- FAT3 | c.1740A>G p.K580= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV53089835, COSV99962212; called by muse, mutect2, varscan2
- FAT4 | c.13284T>C p.P4428= | Silent (SNP) | VAF 68/236 reads (29%) | catalogued as COSV58677388; called by muse, mutect2, varscan2
- G6PC | c.972C>A p.V324= | Silent (SNP) | VAF 79/257 reads (31%) | catalogued as COSV53830491; called by muse, mutect2, varscan2
- GALNT10 | c.1590C>T p.T530= | Silent (SNP) | VAF 32/151 reads (21%) | catalogued as COSV51724258; called by muse, mutect2, varscan2
- GHR | c.1797T>C p.H599= | Silent (SNP) | VAF 45/134 reads (34%) | catalogued as COSV50108707; called by muse, mutect2, varscan2
- GTDC1 | c.963A>T p.G321= | Silent (SNP) | VAF 45/170 reads (26%) | catalogued as COSV53991219; called by muse, mutect2, varscan2
- HDAC9 | c.387C>A p.G129= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV67770159; called by muse, mutect2, varscan2
- HEATR1 | c.4158G>C p.A1386= | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as rs201057500, COSV63980219; called by muse, mutect2, varscan2
- HIVEP2 | c.675T>G p.S225= | Silent (SNP) | VAF 11/231 reads (5%) | catalogued as COSV50007867; called by muse, mutect2
- HSDL1 | c.498C>T p.S166= | Silent (SNP) | VAF 64/262 reads (24%) | catalogued as rs758933678, COSV54740598; called by muse, mutect2, varscan2
- KRT75 | c.1509C>T p.S503= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as COSV52871748; called by muse, mutect2, varscan2
- KRTAP27-1 | c.420T>C p.S140= | Silent (SNP) | VAF 102/426 reads (24%) | catalogued as rs769075531, COSV67001060; called by muse, mutect2, varscan2
- LSAMP | c.630A>G p.Q210= | Silent (SNP) | VAF 34/143 reads (24%) | catalogued as COSV61282536; called by muse, mutect2, varscan2
- MAP2 | c.618T>G p.T206= | Silent (SNP) | VAF 27/129 reads (21%) | catalogued as COSV52285788; called by muse, mutect2, varscan2
- MKRN3 | c.447C>T p.I149= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs569949058, COSV58809281; called by muse, mutect2, varscan2
- MYH7B | c.2172C>T p.N724= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as rs765146045, COSV53417903; called by muse, mutect2, varscan2
- MYL3 | c.576C>A p.I192= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV52767453; called by muse, mutect2, varscan2
- NOP2 | c.1227G>C p.T409= (on ENST00000322166 / NM_001258308.2; = p.T405= on NM_006170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV59109894; called by muse, mutect2, varscan2
- NOTCH3 | c.3573C>T p.C1191= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV54630380; called by muse, mutect2, varscan2
- OR11H1 | c.837T>A p.T279= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as COSV99421729; called by mutect2, varscan2
- OR4A5 | c.874A>C p.R292= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV60521344, COSV60522041; called by muse, mutect2, varscan2
- PCDHA3 | c.1509G>A p.A503= | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as COSV63540090; called by muse, varscan2
- PDHA1 | c.573G>C p.L191= | Silent (SNP) | VAF 84/134 reads (63%) | catalogued as COSV63327936; called by muse, mutect2, varscan2
- PLEKHA5 | c.1170T>C p.N390= | Silent (SNP) | VAF 41/121 reads (34%) | catalogued as COSV54697026; called by muse, mutect2, varscan2
- PRMT8 | c.135C>T p.C45= | Silent (SNP) | VAF 22/408 reads (5%) | catalogued as rs756751414, COSV54212791; called by muse, mutect2
- RDH5 | c.894A>C p.P298= | Silent (SNP) | VAF 33/150 reads (22%) | catalogued as COSV57676139; called by muse, mutect2, varscan2
- RGS22 | c.306A>G p.E102= | Silent (SNP) | VAF 101/454 reads (22%) | catalogued as COSV62659494; called by muse, mutect2, varscan2
- RIMS2 | c.1269T>G p.S423= (on ENST00000666250 / NM_001348490.2; = p.S231= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 39/166 reads (23%) | catalogued as COSV51651026, COSV51655287, COSV51702036; called by muse, mutect2, varscan2
- RUNX3 | c.729C>T p.S243= | Silent (SNP) | VAF 41/140 reads (29%) | catalogued as rs144597350, COSV58244904; called by muse, mutect2, varscan2
- SCNN1B | c.180C>T p.A60= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs768826510, COSV56302846; called by muse, mutect2, varscan2
- SLC2A9 | c.39C>T p.G13= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as rs372879673, COSV53328129; called by muse, mutect2, varscan2
- SPTA1 | c.6405T>C p.S2135= | Silent (SNP) | VAF 79/308 reads (26%) | catalogued as COSV63750863; called by muse, mutect2, varscan2
- SRP19 | c.12T>A p.A4= | Silent (SNP) | VAF 42/221 reads (19%) | catalogued as COSV51583057; called by muse, mutect2, varscan2
- TAS1R2 | c.885C>T p.G295= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs148401055; called by muse, mutect2, varscan2
- TLR4 | c.1752T>G p.T584= (on ENST00000355622 / NM_138554.5; = p.T544= on NM_003266.4) | Silent (SNP) | VAF 32/149 reads (21%) | catalogued as COSV62922767; called by muse, mutect2, varscan2
- TRAM1L1 | c.549C>G p.L183= | Silent (SNP) | VAF 34/229 reads (15%) | catalogued as COSV60291545; called by muse, mutect2, varscan2
- TRPC6 | c.1074C>T p.H358= | Silent (SNP) | VAF 50/230 reads (22%) | catalogued as rs745979751, COSV60252333; called by muse, mutect2, varscan2
- VNN2 | c.1053T>C p.L351= | Silent (SNP) | VAF 65/284 reads (23%) | catalogued as COSV58472021; called by muse, mutect2, varscan2
- WNK2 | c.4512C>T p.D1504= (on ENST00000297954 / NM_001282394.1; = p.D1467= on NM_006648.3) | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs1396555982, COSV52936654; called by muse, mutect2
- ZDHHC20 | c.78C>T p.V26= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs1433700158, COSV57184852; called by muse, mutect2, varscan2
- FBXL21P | n.1070G>A | RNA (SNP) | VAF 52/216 reads (24%) | catalogued as rs746835230, COSV51808498, COSV99778285; called by muse, mutect2, varscan2
- XIRP2 | c.-99A>C | 5'UTR (SNP) | VAF 26/136 reads (19%) | catalogued as COSV54682928, COSV54690067; called by muse, mutect2, varscan2
- ZNF137P | n.1687T>G | RNA (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
